Somatic mutation profile of tumor specimen TCGA-55-7726-01A (aliquot TCGA-55-7726-01A-11D-2167-08) from TCGA case TCGA-55-7726, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 72.4 years (26,451 days).
Specimen TCGA-55-7726-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 451da261-1f93-4fa1-829e-9282bbc6e98a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-7726-10A (Blood Derived Normal), aliquot TCGA-55-7726-10A-01D-2167-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/adf60d7b-0e7c-464f-898f-bb87faee018b

The open-access MAF lists 118 somatic variants for this specimen: 91 protein-altering or splice-affecting, 25 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 75, Silent 25, Nonsense Mutation 10, Frame Shift Del 2, In Frame Del 1, 5'UTR 1, Splice Site 1, Nonstop Mutation 1, Splice Region 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.5170G>A p.E1724K | Missense Mutation (SNP) | VAF 33/189 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1567265131, CM104889, COSV52116547, COSV52143983; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DIS3 | c.1463A>C p.D488A | Missense Mutation (SNP) | VAF 8/44 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66706118, COSV66708289; called by muse, mutect2, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 24/43 reads (56%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PITX2 | c.329C>T p.P110L (on ENST00000354925 / NM_001204397.1; = p.P117L on NM_000325.6) | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519484, CM024243, CM064163, COSV60742522; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.423C>A p.C141* | Nonsense Mutation (SNP) | VAF 12/58 reads (21%) | hotspot (GDC flag); catalogued as COSV52671863, COSV52706449, COSV52741627, COSV52827803; called by muse, mutect2, varscan2
- ACVRL1 | c.785C>G p.S262* | Nonsense Mutation (SNP) | VAF 19/81 reads (23%) | catalogued as COSV66361449; called by muse, mutect2, varscan2
- ADAM22 | c.1566+2T>A p.X522_splice | Splice Site (SNP) | VAF 3/35 reads (9%) | catalogued as COSV55992629; called by muse, mutect2
- ADAMTS20 | c.2038G>A p.G680R | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs1213732576, COSV67141094; called by muse, mutect2, varscan2
- ANAPC2 | c.1183G>C p.D395H | Missense Mutation (SNP) | VAF 44/210 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60572851; called by muse, mutect2, varscan2
- ANKEF1 | c.1481C>G p.S494* | Nonsense Mutation (SNP) | VAF 11/130 reads (8%) | catalogued as COSV65694035; called by muse, mutect2
- ANKRD30A | c.1367A>T p.E456V (on ENST00000611781; = p.E400V on NM_052997.2) | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as COSV64623583; called by muse, varscan2
- ARAP2 | c.1589C>G p.S530C | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV58293700; called by muse, mutect2, varscan2
- ARID2 | c.5393C>G p.S1798* | Nonsense Mutation (SNP) | VAF 7/49 reads (14%) | catalogued as COSV100535968, COSV57616604; called by muse, mutect2, varscan2
- ARL2 | c.376A>G p.K126E | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV55861926; called by muse, mutect2
- ATP11A | c.2320G>C p.D774H | Missense Mutation (SNP) | VAF 31/147 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.89); catalogued as COSV52126799; called by muse, mutect2, varscan2
- BICDL1 | c.1169C>T p.S390L | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57494679; called by muse, varscan2
- BOC | c.881C>G p.S294* | Nonsense Mutation (SNP) | VAF 16/67 reads (24%) | catalogued as COSV56359084; called by muse, mutect2, varscan2
- CCDC73 | c.2329C>G p.L777V | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.495); catalogued as COSV58806337; called by muse, mutect2, varscan2
- CFAP91 | c.530C>T p.S177F | Missense Mutation (SNP) | VAF 47/259 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.568); catalogued as rs1424469605, COSV56345490; called by muse, mutect2, varscan2
- CNGA4 | c.1576G>C p.A526P | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as COSV66007274; called by muse, mutect2, varscan2
- CRAMP1 | c.1092G>C p.Q364H | Missense Mutation (SNP) | VAF 39/76 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV51966927; called by muse, mutect2, varscan2
- CREBBP | c.4246G>C p.E1416Q | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52143552, COSV52143999; called by muse, mutect2, varscan2
- DCAF15 | c.1031C>A p.P344H | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.138); catalogued as COSV54334204; called by muse, mutect2
- DMBT1 | c.7405G>T p.A2469S (on ENST00000338354 / NM_001377530.1; = p.A1712S on NM_004406.3) | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.07); catalogued as COSV57566955; called by muse, mutect2
- FAF1 | c.209G>C p.S70T | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.024); catalogued as COSV65644943; called by muse, mutect2, varscan2
- FAM89B | c.529C>T p.R177C (on ENST00000530349 / NM_001098785.2; = p.R164C on NM_152832.3) | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as rs1320908937, COSV57080371; called by muse, mutect2, varscan2
- FOXP2 | c.282G>A p.M94I | Missense Mutation (SNP) | VAF 13/225 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV63495346; called by muse, mutect2
- FRAS1 | c.5650G>T p.E1884* | Nonsense Mutation (SNP) | VAF 6/14 reads (43%) | catalogued as COSV53655885, COSV99078045; called by muse, mutect2, varscan2
- GCN1 | c.958C>G p.L320V | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV56115945; called by muse, mutect2, varscan2
- GFRA1 | c.676C>T p.R226* | Nonsense Mutation (SNP) | VAF 9/62 reads (15%) | catalogued as rs191814086; called by muse, mutect2, varscan2
- GORASP1 | c.1291G>A p.D431N | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs750828063, COSV56534815; called by muse, mutect2, varscan2
- GRIN3A | c.1369G>A p.V457I | Missense Mutation (SNP) | VAF 46/215 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs777473704, COSV62452525; called by muse, mutect2, varscan2
- HDLBP | c.1523G>T p.R508L | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.025); catalogued as COSV60501555, COSV60501962; called by muse, mutect2, varscan2
- HMCN1 | c.14672C>T p.A4891V | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV54948567; called by muse, mutect2, varscan2
- HTT | c.4428G>T p.L1476F | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61869160, COSV61870819; called by muse, mutect2, varscan2
- ITGA9 | c.1324C>T p.P442S | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT tolerated (0.73); PolyPhen benign (0.265); catalogued as COSV53252161, COSV53254557; called by muse, mutect2, varscan2
- ITGAL | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV100776106, COSV63324821; called by muse, mutect2, varscan2
- JADE1 | c.2279A>T p.Q760L | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV56910004; called by muse, mutect2
- KAT14 | c.721G>C p.E241Q | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.815); catalogued as COSV66609554; called by muse, mutect2, varscan2
- KIR3DL1 | c.1010G>T p.R337I | Missense Mutation (SNP) | VAF 14/161 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as rs748525951, COSV58494889, COSV58496931; called by muse, mutect2
- KLHL20 | c.656C>G p.S219C | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.086); catalogued as COSV52942243; called by muse, mutect2, varscan2
- KMT5B | c.2032G>C p.V678L | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.019); catalogued as COSV58570301; called by muse, mutect2, varscan2
- LINGO3 | c.1525G>C p.E509Q | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.58); PolyPhen benign (0.058); catalogued as COSV68260977, COSV68261966; called by muse, mutect2
- LRRC14 | c.1121_1124del p.E374Vfs*15 | Frame Shift Del (DEL) | VAF 10/57 reads (18%) | catalogued as rs760735477; called by mutect2, pindel, varscan2
- MAD1L1 | c.1583G>A p.R528Q | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.024); catalogued as rs201537051; called by muse, mutect2, varscan2
- MAP4K1 | c.663C>T p.L221= | Splice Region (SNP) | VAF 16/47 reads (34%) | catalogued as rs752231895, COSV67713127, COSV67713634; called by muse, mutect2, varscan2
- MCCC1 | c.1888G>C p.D630H | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV55609862, COSV55612528; called by muse, mutect2, varscan2
- MTMR1 | c.1001C>A p.S334* | Nonsense Mutation (SNP) | VAF 10/72 reads (14%) | catalogued as COSV64892189; called by muse, mutect2, varscan2
- MYH13 | c.1348G>T p.D450Y | Missense Mutation (SNP) | VAF 48/175 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); catalogued as COSV52825296, COSV52846006; called by muse, mutect2, varscan2
- MYO5A | c.4441A>T p.K1481* | Nonsense Mutation (SNP) | VAF 34/191 reads (18%) | catalogued as COSV62565681; called by muse, mutect2, varscan2
- NCKAP5 | c.2713G>A p.D905N | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as COSV58480057; called by muse, mutect2, varscan2
- NEDD9 | c.1261G>C p.E421Q | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as COSV65223734; called by muse, mutect2, varscan2
- NR2E1 | c.632T>C p.L211S | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.077); catalogued as COSV100934649; called by muse, mutect2, varscan2
- NUP98 | c.265A>G p.N89D | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.218); catalogued as COSV61439881; called by muse, mutect2
- OOSP2 | c.253G>C p.E85Q | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.844); catalogued as COSV53930319; called by muse, mutect2, varscan2
- OR4N5 | c.298C>G p.Q100E | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV61321454; called by muse, mutect2, varscan2
- PCDH1 | c.1214C>G p.S405* | Nonsense Mutation (SNP) | VAF 6/118 reads (5%) | catalogued as COSV54620512; called by muse, mutect2
- PHLDA1 | c.1205G>C p.*402Sext*11 | Nonstop Mutation (SNP) | VAF 12/82 reads (15%) | catalogued as COSV56997009, COSV56998460; called by muse, mutect2, varscan2
- PHLDA1 | c.772G>C p.E258Q | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV56997244, COSV56998470; called by muse, mutect2, varscan2
- PHLDA1 | c.331G>C p.E111Q | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV56998478; called by muse, mutect2, varscan2
- PTPRZ1 | c.3703A>G p.M1235V | Missense Mutation (SNP) | VAF 9/168 reads (5%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.001); catalogued as COSV66431638; called by muse, mutect2
- QTRT1 | c.1021G>A p.A341T | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.756); catalogued as rs756496433, COSV51553239; called by muse, mutect2, varscan2
- RHOBTB3 | c.1148A>G p.K383R | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.868); catalogued as COSV66103179; called by muse, mutect2, varscan2
- RICTOR | c.3561G>C p.K1187N | Missense Mutation (SNP) | VAF 26/219 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.148); catalogued as rs753433555, COSV57132166; called by muse, mutect2, varscan2
- RNF41 | c.943G>C p.E315Q | Missense Mutation (SNP) | VAF 41/201 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV61505341; called by muse, varscan2
- ROCK1 | c.1664G>C p.R555T | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.652); catalogued as COSV67699994; called by muse, mutect2, varscan2
- RPGRIP1L | c.3857G>A p.G1286D | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.025); catalogued as rs755820734, COSV50920527; called by muse, mutect2, varscan2
- SALL4 | c.1387G>C p.D463H | Missense Mutation (SNP) | VAF 25/181 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs770056012, COSV53856784; called by muse, mutect2, varscan2
- SEPTIN5 | c.782G>A p.R261Q | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV63531058; called by muse, mutect2, varscan2
- SERPINF2 | c.1113G>C p.Q371H | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.02); catalogued as COSV60666031; called by muse, mutect2, varscan2
- SLC14A2 | c.662C>A p.S221Y | Missense Mutation (SNP) | VAF 58/237 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.642); catalogued as COSV54915384; called by muse, mutect2, varscan2
- SNRNP200 | c.821G>A p.R274H | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs754858849, COSV60492831; called by muse, mutect2, varscan2
- SPEG | c.2570A>C p.N857T | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs772701981; called by muse, mutect2, varscan2
- TAPT1 | c.834G>A p.M278I | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV58824650; called by muse, mutect2, varscan2
- TARBP1 | c.2425G>C p.V809L | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.058); catalogued as COSV50213214; called by muse, mutect2, varscan2
- TIMP3 | c.473C>T p.T158I | Missense Mutation (SNP) | VAF 85/158 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.413); catalogued as COSV56667180; called by muse, mutect2, varscan2
- TLR4 | c.916T>G p.C306G (on ENST00000355622 / NM_138554.5; = p.C266G on NM_003266.4) | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV62924483; called by muse, mutect2, varscan2
- TRIOBP | c.6205G>C p.E2069Q (on ENST00000644935 / NM_001039141.3; = p.E356Q on NM_007032.5) | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.404); catalogued as COSV58526400; called by muse, varscan2
- TSHZ3 | c.661G>A p.A221T | Missense Mutation (SNP) | VAF 20/190 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.537); catalogued as rs768951623, COSV53665675; called by muse, mutect2
- TTC7B | c.705G>C p.L235F | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV60640561; called by muse, mutect2
- UGGT1 | c.604A>T p.I202F | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.03); catalogued as rs768872494, COSV52142819; called by muse, mutect2, varscan2
- USP33 | c.1438G>C p.D480H | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62471860; called by muse, varscan2
- USP34 | c.6114G>A p.M2038I | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.156); catalogued as COSV68408058; called by muse, mutect2
- USP8 | c.920G>T p.C307F | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as COSV56169168; called by muse, mutect2, varscan2
- VPS13C | c.10187A>C p.Q3396P (on ENST00000644861 / NM_020821.3; = p.Q3353P on NM_017684.5) | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV51429013; called by muse, mutect2
- XIRP2 | c.7195C>G p.Q2399E (on ENST00000628543; = p.Q2574E on NM_152381.6) | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54740058; called by muse, mutect2, varscan2
- ZBBX | c.1650C>G p.I550M | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.191); catalogued as COSV56803645; called by muse, mutect2, varscan2
- ZC3H14 | c.2142C>G p.F714L | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51768669, COSV51774447; called by muse, mutect2, varscan2
- CD37 | c.415del p.A139Pfs*29 | Frame Shift Del (DEL) | VAF 13/59 reads (22%) | called by mutect2, pindel, varscan2
- NBEAL1 | c.5641_5643del p.E1881del | In Frame Del (DEL) | VAF 12/38 reads (32%) | called by pindel, varscan2
- TRAV26-1 | c.113C>G p.P38R | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); called by muse, mutect2
- ADIPOR1 | c.759G>A p.A253= | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as rs145759019; called by muse, mutect2, varscan2
- API5 | c.6G>C p.P2= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV66635141, COSV66635464; called by muse, mutect2, varscan2
- APOBEC3A | c.360G>A p.V120= | Silent (SNP) | VAF 54/208 reads (26%) | catalogued as rs764951988, COSV50779768; called by muse, mutect2, varscan2
- BCL7C | c.33G>A p.R11= | Silent (SNP) | VAF 6/86 reads (7%) | catalogued as COSV53063765; called by muse, mutect2
- BTG1 | c.273T>C p.S91= | Silent (SNP) | VAF 23/119 reads (19%) | catalogued as COSV55460760; called by muse, mutect2, varscan2
- EVC | c.1176G>A p.E392= | Silent (SNP) | VAF 18/68 reads (26%) | catalogued as rs752626166, COSV53839117; called by muse, mutect2, varscan2
- F8 | c.792G>C p.L264= | Silent (SNP) | VAF 30/104 reads (29%) | catalogued as COSV64279628; called by muse, mutect2, varscan2
- FAM122C | c.27T>G p.G9= | Silent (SNP) | VAF 23/174 reads (13%) | catalogued as COSV66196636; called by muse, mutect2, varscan2
- FHOD1 | c.1674G>A p.L558= | Silent (SNP) | VAF 9/82 reads (11%) | catalogued as COSV50772842; called by muse, mutect2, varscan2
- GAL3ST2 | c.264A>G p.S88= | Silent (SNP) | VAF 10/116 reads (9%) | catalogued as COSV51951972; called by muse, mutect2
- KCNJ15 | c.792G>A p.L264= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as COSV100154097, COSV60810374; called by muse, mutect2, varscan2
- LAMA5 | c.3531C>T p.A1177= | Silent (SNP) | VAF 10/150 reads (7%) | catalogued as rs142357165, COSV53374583; called by muse, mutect2
- LRIG2 | c.744G>C p.R248= | Silent (SNP) | VAF 15/119 reads (13%) | catalogued as COSV63164628; called by muse, mutect2, varscan2
- MCM5 | c.1929C>T p.L643= | Silent (SNP) | VAF 61/213 reads (29%) | catalogued as COSV53348688; called by muse, mutect2, varscan2
- MLH1 | c.1650C>G p.L550= | Silent (SNP) | VAF 17/78 reads (22%) | catalogued as COSV51625443; called by muse, mutect2, varscan2
- MRPL4 | c.720C>T p.F240= | Silent (SNP) | VAF 11/107 reads (10%) | catalogued as COSV53446789; called by muse, mutect2, varscan2
- MSI2 | c.390C>T p.F130= | Silent (SNP) | VAF 27/99 reads (27%) | catalogued as rs201726045, COSV52363733; called by muse, mutect2, varscan2
- MTSS1 | c.819C>G p.V273= | Silent (SNP) | VAF 15/64 reads (23%) | catalogued as COSV61500768; called by muse, mutect2, varscan2
- NLRP8 | c.1077G>A p.T359= | Silent (SNP) | VAF 34/102 reads (33%) | catalogued as rs1000244011, COSV52587062; called by muse, mutect2, varscan2
- NTNG2 | c.639C>T p.F213= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as rs371305436; called by muse, mutect2, varscan2
- RADIL | c.321C>T p.A107= | Silent (SNP) | VAF 12/106 reads (11%) | catalogued as rs372501424; called by muse, varscan2
- SHPRH | c.375T>A p.P125= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV51619341; called by muse, mutect2, varscan2
- SMG5 | c.1500T>C p.S500= | Silent (SNP) | VAF 20/139 reads (14%) | catalogued as COSV62438348; called by muse, mutect2, varscan2
- SRCAP | c.3279G>A p.L1093= | Silent (SNP) | VAF 27/151 reads (18%) | catalogued as COSV52682590, COSV99351488; called by muse, mutect2, varscan2
- STRADA | c.879C>T p.N293= (on ENST00000336174 / NM_001363786.1; = p.N256= on NM_153335.6) | Silent (SNP) | VAF 25/108 reads (23%) | catalogued as rs147552949; called by muse, mutect2, varscan2
- H4C3 | c.-1C>T | 5'UTR (SNP) | VAF 15/82 reads (18%) | catalogued as rs747940169, COSV100619681; called by muse, mutect2, varscan2
- MCF2 | chrX:139646843 C>A | 5'Flank (SNP) | VAF 7/23 reads (30%) | catalogued as COSV100645277; called by muse, mutect2, varscan2
